Surgical pathology report (de-identified scan), TCGA case TCGA-57-1993, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-57-1993-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN INFO

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Right oophorectomy:

Serous adenocarcinoma.

Grade: III.

Tumor show near total replacement of specimen.

Size: 10.6 cm in greatest dimension.

Lymphovascular space invasion: Not identified.

Right fallopian tube - Focal mucosal and serosal involvement by serous adenocarcinoma.

B. Omentum, excision:

Metastatic serous adenocarcinoma.

C. Ovary, left oophorectomy:

Serous adenocarcinoma.

Grade: III

Focal calcified fibrous nodule with adjacent necrotic tissue.

Tumor shows near total replacement of ovary.

Size: 9.1 cm in greatest dimension.

Lymphovascular space invasion present.

Left fallopian tube - not identified grossly or histologically.

D. Peritoneum, left gutter, biopsy:

Metastatic adenocarcinoma.

E. Peritoneum, right gutter, biopsy:

Metastatic adenocarcinoma.

F. Diaphragm, biopsy:

Metastatic adenocarcinoma.

G. Sigmoid mesenteric implant, biopsy:

Metastatic adenocarcinoma.

H. Uterus, hysterectomy:

Uterine cervix -

Microscopic focus of high grade serous carcinoma. at transition zone.

Multiple foci of metastatic tumor within intravascular space and submucosal connective tissue.

Benign endocervical polyp.

Endometrium -

Endometrial polyp.

Background atrophy.

Myometrium -

Foci of metastatic adenocarcinoma within vessels and connective tissue.

Multiple hyalinized leiomyomas.

Uterine serosa -

Foci of metastatic adenocarcinoma.

[page 2 of 3]
DIAGNOSIS

pTNM stage: T3NXMX

COMMENTS:

This case has been reviewed by Dr.

who agrees with the diagnosis.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right ovary
- B. Omentum
- C. Left ovary
- D. Left gutter
- E. Right gutter
- F. Biopsy of diaphragm
- G. Sigmoid mesenteric implant
- H. Uterus

SPECIMEN DATA

GROSS DESCRIPTION:

A. Part A received in formalin labeled _____ and #1 is a 10.6 x 10.1 x 4.4 cm irregular to ovoid, shaggy tan pink to red purple membranous tissue, with an attached 2.8 x 0.6 cm tubular tissue. The cut surface of the tissue consists of a 10.8 cm cyst. The remainder of the cut surface consists of tan pink to gray white soft tissue. The attached tubular tissue has a tan pink serosa and a pinpoint lumen, consistent with probable fallopian tube.

Also received in the same container is a 4.6 x 3.1 x 1.5 cm irregular gray white soft tissue, consistent with possible ovary. The outer surface is lobulated shaggy and gray white. The cut surface is gray white.

The specimen is serially sectioned and representative sections are submitted for frozen section and the frozen section residue is submitted in block 1. Additional representative sections are submitted as labeled: _____ membranous tissue block 8 tubular tissue attached to membranous tissue blocks 9 and 10 additional tissue. The blocks are labeled _____. Also received in the same container are three orange cassettes labeled A C and D and a green and yellow cassette labeled _____ for genomic research study.

B. Part B received in formalin labeled _____ and #2 omentum is a 15.8 x 12.1 x 3.2 cm aggregate of fibroadipose tissue, consistent with omentum. The cut surface consists of predominantly yellow lobulated adipose tissue, with a minimal amount of gray white fibrous tissue. There are several firm gray white areas on the cut surface. The specimen is serially sectioned and representative sections are submitted in one cassette labeled _____.

C. Part C received in formalin labeled _____ and #3 left ovary is a 9.1 x 4.7 x 2.6 cm irregular, shaggy tan red soft tissue. The cut surface consists of focally gritty gray white to tan soft tissue. There is a 1.1 x 0.6 x 0.5 cm hard nodule within the cut surface. No ovarian stroma is identified. A fallopian tube is not identified. The specimen is serially sectioned and representative sections are submitted in six cassettes, with the hard nodule submitted in cassette 6, following decalcification. The cassettes are labeled _____.

D. Part D received in formalin labeled _____ and #4 left gutter is an 8.4 x 3.6 x 0.4 cm irregular gray white to tan red membranous tissue, with attached adipose tissue. The specimen is serially sectioned and representative sections are submitted in one cassette labeled _____.

E. Part E is received in formalin labeled _____ and #5 right gutter is a 7.4 x 5.2 x 1.1 cm irregular, granular gray white to tan red membranous tissue, with attached adipose tissue. The specimen is serially sectioned and representative sections are submitted in one cassette labeled _____.

F. Part F received in formalin labeled _____ and #6 biopsy diaphragm is a 2.7 x 1.8 x 0.5 cm aggregate of gray white to red soft tissue, which is serially sectioned and submitted in its entirety in one cassette labeled _____.

G. Part G received in formalin labeled _____ and #7 sigmoid mesenteric implant is a 1.3 x 1.1 x 0.4 cm irregular, gritty gray white soft tissue,

[page 3 of 3]
with attached adipose tissue, which is serially sectioned and submitted in its entirety in one cassette labeled ' [REDACTED]

H. Part H received in formalin labeled [REDACTED] and #8 uterus is a 52 gram previously opened hysterectomy specimen, consisting of a 4.7 x 4.3 x 2.6 cm uterine body and a 2.4 x 1.8 x 1.5 cm cervix. The specimen can not be oriented. The serosa is shaggy and tan pink to red. The exocervix is smooth and gray white with a 0.1 cm circular os. The endocervical canal is glistening tan and 1.6 cm in length. There is a 0.6 x 0.5 cm endocervical polyp. The identifiable probable endometrium is glistening tan and averages 0.1 cm in thickness. There is a 1.2 cm cystic gray white possible endometrial polyp. The myometrium is trabeculated, tan pink, and averages 1.3 cm in thickness. There are multiple intramural whorled gray white dense nodules, ranging from 0.4 to 1.8 cm in greatest dimension. No areas of hemorrhage or necrosis are identified in the nodules. The largest nodule has a gritty, hard gray white to yellow cut surface. The specimen is serially sectioned and representative sections are submitted as labeled: blocks 1 and 2 anterior and posterior cervix block 3 endocervical polyp, entirely submitted blocks 4 and 5 endomyometrium to include probable endometrial polyp in its entirety block 6 myometrial nodules block 7 largest myometrial nodule, following decalcification block 8 serosa. The blocks are labeled

INTRA-OPERATIVE CONSULTATION:

FSA: 'Adenocarcinoma: Favor ovarian primary' per Dr [REDACTED]

Source: NCI Genomic Data Commons file e400c202-bd23-4444-879e-9eec5315341b (TCGA-57-1993.55495E3A-6052-4FB1-B8A9-10B54DCDFBEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).